Somatic mutation profile of tumor specimen TCGA-AA-3685-01A (aliquot TCGA-AA-3685-01A-02W-0900-09) from TCGA case TCGA-AA-3685, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 69.8 years (25,506 days).
Specimen TCGA-AA-3685-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87e0dddc-d72f-41be-aed2-fa323cf0b92a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3685-10A (Blood Derived Normal), aliquot TCGA-AA-3685-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94dff36d-b83c-4cd9-a19d-f5b6ee952a30

The open-access MAF lists 92 somatic variants for this specimen: 72 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 18, Nonsense Mutation 8, Frame Shift Ins 4, Splice Site 3, Frame Shift Del 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 56/108 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADCY10 | c.3007+2T>C p.X1003_splice | Splice Site (SNP) | VAF 24/100 reads (24%) | catalogued as rs751771991, COSV100896498; called by muse, mutect2, varscan2
- ANO2 | c.1684G>A p.A562T (on ENST00000356134 / NM_001278597.3; = p.A566T on NM_001278596.3) | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.598); catalogued as rs779424459, COSV59006178, COSV59018107; called by muse, mutect2, varscan2
- APC | c.2932C>T p.Q978* | Nonsense Mutation (SNP) | VAF 49/198 reads (25%) | catalogued as CM995165, COSV57334436; called by muse, mutect2, varscan2
- APC | c.4108A>T p.K1370* | Nonsense Mutation (SNP) | VAF 140/320 reads (44%) | catalogued as CM920054, COSV57335316; called by muse, mutect2, varscan2
- ATP2A3 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs772945810, COSV59228588, COSV99989339; called by muse, mutect2, varscan2
- ATP9A | c.2419G>T p.G807* | Nonsense Mutation (SNP) | VAF 184/290 reads (63%) | catalogued as COSV58768540; called by muse, mutect2, varscan2
- C22orf23 | c.101G>C p.R34T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV50778070; called by muse, mutect2, varscan2
- CADPS | c.3225G>T p.Q1075H | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV51888558; called by muse, mutect2, varscan2
- CGB2 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100031736; called by muse, mutect2
- COL11A1 | c.3275C>T p.P1092L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62188193, COSV62191763; called by muse, mutect2
- DAB2 | c.2209C>T p.P737S | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.435); catalogued as COSV57916098; called by muse, mutect2, varscan2
- DGKB | c.1496C>A p.T499N | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs949395139, COSV51796606, COSV99342023; called by muse, mutect2
- DHRSX | c.121C>T p.R41* | Nonsense Mutation (SNP) | VAF 45/260 reads (17%) | catalogued as rs772173053, COSV58135537; called by mutect2, varscan2
- ELMO1 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1475312411, COSV60311096; called by muse, mutect2, varscan2
- ENPP1 | c.1406-1G>A p.X469_splice | Splice Site (SNP) | VAF 68/223 reads (30%) | catalogued as COSV100719328; called by muse, mutect2, varscan2
- EPHB1 | c.1925G>A p.G642D | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs768101201, COSV67664630; called by muse, mutect2, varscan2
- FRYL | c.1659G>T p.K553N | Missense Mutation (SNP) | VAF 49/202 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51951929; called by muse, mutect2, varscan2
- GALNT9 | c.1453G>A p.G485S (on ENST00000328957 / NM_001122636.2; = p.G119S on NM_021808.3) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs775412981, COSV61100647; called by muse, mutect2, varscan2
- GHRHR | c.303G>C p.W101C | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58197141; called by muse, mutect2, varscan2
- GPR132 | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs754386954, COSV61678080; called by muse, mutect2, varscan2
- H4C5 | c.276G>C p.K92N | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs754130463, COSV63486830; called by muse, mutect2, varscan2
- HAS1 | c.1670C>T p.T557M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs1217318210, COSV55788312; called by muse, mutect2
- HEATR5A | c.5009G>A p.G1670E | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as COSV101119488; called by muse, mutect2
- HEY2 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100856271; called by muse, mutect2, varscan2
- JHY | c.841dup p.R281Kfs*35 | Frame Shift Ins (INS) | VAF 88/242 reads (36%) | catalogued as rs974240509; called by mutect2, varscan2
- KCNK13 | c.580G>A p.V194M | Missense Mutation (SNP) | VAF 97/166 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757739727, COSV56412467, COSV99965591; called by muse, mutect2, varscan2
- KLHL7 | c.1325A>G p.N442S (on ENST00000339077 / NM_001031710.3; = p.N394S on NM_018846.5) | Missense Mutation (SNP) | VAF 143/231 reads (62%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.839); catalogued as rs771084569, COSV59162399; called by muse, mutect2, varscan2
- KRTAP10-8 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); catalogued as rs782250995, COSV100554880, COSV58166672; called by muse, mutect2, varscan2
- LAMA3 | c.9658G>A p.D3220N (on ENST00000313654 / NM_198129.4; = p.D1611N on NM_000227.6) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52537504; called by muse, mutect2, varscan2
- LPP | c.1306G>T p.V436F | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57099268; called by muse, mutect2, varscan2
- LRP1B | c.4856G>A p.R1619H | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774644795, COSV67242351; called by muse, mutect2, varscan2
- LRRC41 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 75/214 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV58440738; called by muse, mutect2, varscan2
- MAGIX | c.451C>G p.L151V | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); catalogued as COSV66256194; called by muse, mutect2, varscan2
- MCCC2 | c.804-1G>C p.X268_splice | Splice Site (SNP) | VAF 37/102 reads (36%) | catalogued as COSV100039747; called by muse, mutect2, varscan2
- MDN1 | c.3094G>C p.G1032R | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV65524093, COSV65524266; called by muse, mutect2, varscan2
- MYH6 | c.4769G>A p.R1590H | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs377473560; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NALCN | c.2110G>C p.D704H | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.995); catalogued as COSV99212703; called by muse, mutect2
- NAV3 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 46/502 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.368); catalogued as COSV57080242, COSV57091865; called by muse, mutect2
- NRXN1 | c.4016C>G p.P1339R | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV60506979, COSV60525112; called by muse, mutect2, varscan2
- NSUN2 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as COSV52955362; called by muse, mutect2, varscan2
- OR51B5 | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 29/239 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56176516; called by muse, mutect2, varscan2
- OR5H6 | c.882C>A p.Y294* (on ENST00000642105; = p.Y278* on NM_001005479.2) | Nonsense Mutation (SNP) | VAF 85/190 reads (45%) | catalogued as COSV67351709; called by muse, mutect2
- PASK | c.1811dup p.S605Qfs*12 | Frame Shift Ins (INS) | VAF 6/50 reads (12%) | catalogued as rs769655744; called by mutect2, pindel
- PAX3 | c.1271C>T p.T424M | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.302); catalogued as rs770087251, CD102011, COSV60586905; called by muse, mutect2, varscan2
- PCDH11X | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 85/120 reads (71%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs748002525, COSV53441785; called by muse, mutect2, varscan2
- POLR1G | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.27); catalogued as rs1421404462, COSV50004584; called by muse, mutect2, varscan2
- PRR5L | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 157/277 reads (57%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs751977077, COSV61122304; called by muse, mutect2, varscan2
- RASGRF1 | c.2839C>T p.R947C | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs368623142; called by muse, mutect2, varscan2
- RNF20 | c.1705C>T p.R569* | Nonsense Mutation (SNP) | VAF 57/208 reads (27%) | catalogued as rs535787053, COSV66661517; called by muse, mutect2, varscan2
- RP1 | c.431T>C p.V144A | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV55120184; called by muse, mutect2
- RP1 | c.5270C>T p.S1757L | Missense Mutation (SNP) | VAF 48/224 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55120193; called by muse, mutect2, varscan2
- SEC24B | c.2420G>A p.R807H | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770989941, COSV54498557, COSV54502109; called by muse, mutect2, varscan2
- SNRNP200 | c.2369C>A p.T790N | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.103); catalogued as COSV60491631; called by muse, mutect2, varscan2
- TBC1D24 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs368575199; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBX18 | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 153/361 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs571410094, COSV63736132; called by muse, mutect2, varscan2
- TMEM108 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.386); catalogued as rs199967106, COSV58868307; called by muse, mutect2, varscan2
- TNS1 | c.4724C>A p.P1575H | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV50718985; called by muse, mutect2, varscan2
- TTC21B | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs781486283, COSV54632170; called by muse, mutect2
- TTN | c.76481C>A p.T25494N (on ENST00000591111; = p.T18070N on NM_003319.4) | Missense Mutation (SNP) | VAF 15/78 reads (19%) | PolyPhen benign (0.003); catalogued as COSV60164006; called by muse, mutect2, varscan2
- UBA2 | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs575391206, COSV55827838; called by muse, mutect2, varscan2
- USF3 | c.436A>C p.K146Q | Missense Mutation (SNP) | VAF 213/461 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV57074640; called by muse, mutect2, varscan2
- VANGL1 | c.1532C>T p.S511F | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV100048748; called by muse, mutect2
- VANGL2 | c.805C>T p.Q269* | Nonsense Mutation (SNP) | VAF 124/341 reads (36%) | catalogued as COSV63604826; called by muse, mutect2, varscan2
- ZNF480 | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 32/218 reads (15%) | catalogued as rs113675780, COSV57996920; called by muse, mutect2, varscan2
- ZNF543 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.932); catalogued as rs1442621550, COSV100386590; called by muse, mutect2
- CD177 | c.773C>A p.T258N | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CXCL16 | c.365dup p.I123Nfs*47 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by pindel, varscan2
- IGHM | c.431T>C p.I144T | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- L2HGDH | c.816C>G p.C272W | Missense Mutation (SNP) | VAF 164/278 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO1B | c.2842_2843insGT p.F948Cfs*47 (on ENST00000304164; = p.F890Cfs*47 on NM_012223.5) | Frame Shift Ins (INS) | VAF 58/169 reads (34%) | called by mutect2, pindel, varscan2
- STIM2 | c.1231del p.H411Tfs*13 | Frame Shift Del (DEL) | VAF 59/174 reads (34%) | called by mutect2, pindel, varscan2
- ADD2 | c.273G>A p.A91= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as rs782016516, COSV52464319; called by muse, mutect2, varscan2
- CFAP100 | c.996G>A p.T332= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs373852507; called by muse, mutect2, varscan2
- DPYSL5 | c.138C>T p.G46= | Silent (SNP) | VAF 20/265 reads (8%) | catalogued as rs761018813, COSV56511644; called by muse, mutect2
- KCNJ4 | c.171C>T p.Y57= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV57857702; called by muse, mutect2, varscan2
- KIF22 | c.1311G>A p.P437= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs1043807128, COSV99360757; called by muse, mutect2, varscan2
- LRRTM3 | c.303C>T p.D101= | Silent (SNP) | VAF 56/324 reads (17%) | catalogued as COSV63671705; called by muse, mutect2, varscan2
- MAPK14 | c.642C>T p.A214= | Silent (SNP) | VAF 115/197 reads (58%) | catalogued as rs201451587, COSV57696481; called by muse, mutect2, varscan2
- NCAN | c.3930G>T p.T1310= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV53053638; called by muse, mutect2, varscan2
- NR3C1 | c.852C>T p.I284= | Silent (SNP) | VAF 44/191 reads (23%) | catalogued as rs1364105957, COSV51544414; called by muse, mutect2, varscan2
- OR6K2 | c.318C>T p.T106= | Silent (SNP) | VAF 97/350 reads (28%) | catalogued as rs770576605, COSV62743079, COSV62743123; called by muse, mutect2, varscan2
- PARP12 | c.498C>T p.H166= | Silent (SNP) | VAF 65/378 reads (17%) | catalogued as rs760666332, COSV54933698; called by muse, mutect2, varscan2
- PCDHB3 | c.1629C>T p.S543= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV50586619; called by muse, mutect2, varscan2
- PCDHGA1 | c.2232C>T p.D744= | Silent (SNP) | VAF 31/159 reads (19%) | catalogued as COSV65296209; called by muse, mutect2, varscan2
- PGLYRP2 | c.1110G>A p.K370= | Silent (SNP) | VAF 36/223 reads (16%) | catalogued as COSV52995417; called by muse, mutect2, varscan2
- PPFIA2 | c.2070C>G p.L690= | Silent (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- RPL12 | c.9G>T p.P3= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV55940969, COSV55941963; called by muse, mutect2
- SPEN | c.8400G>A p.A2800= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs774526480, COSV65363939; called by muse, mutect2, varscan2
- TGM5 | c.1473T>A p.P491= (on ENST00000220420 / NM_201631.4; = p.P409= on NM_004245.4) | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as COSV55010730; called by muse, mutect2, varscan2
- CSF2RA | c.*36G>A | 3'UTR (SNP) | VAF 62/245 reads (25%) | catalogued as rs144367097, COSV62625342; called by muse, mutect2, varscan2
- KIR3DX1 | n.940C>A | RNA (SNP) | VAF 62/130 reads (48%) | catalogued as COSV55599334; called by muse, mutect2, varscan2
